Somatic mutation profile of tumor specimen 0DAS6G from CCDI case PBBKMK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,435 days).
Specimen 0DAS6G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03ef44ec-7654-4a44-97cd-626344206429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAS6H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fd839d4-06f8-4188-8e4c-2f9914bb13cd

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RGL1 | c.980C>T p.S327F (on ENST00000360851 / NM_001297672.2; = p.S362F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868356084, COSV58987925; called by muse, mutect2, varscan2
- CARMIL2 | c.1333A>C p.T445P | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- RPL7 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
